Somatic mutation profile of tumor specimen TCGA-FX-A3TO-01A (aliquot TCGA-FX-A3TO-01A-11D-A228-09) from TCGA case TCGA-FX-A3TO, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 87.2 years (31,868 days).
Specimen TCGA-FX-A3TO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 133676db-802d-4c51-b105-03246cd28e58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A3TO-10A (Blood Derived Normal), aliquot TCGA-FX-A3TO-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b60fb89f-95fc-4669-b7cb-f09d1326a507

The open-access MAF lists 69 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Nonsense Mutation 4, Intron 2, Nonstop Mutation 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 36/43 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1856A>C p.Q619P | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99445680; called by muse, mutect2, varscan2
- ATP2A3 | c.2382G>A p.W794* | Nonsense Mutation (SNP) | VAF 35/255 reads (14%) | catalogued as COSV99988719; called by muse, mutect2, varscan2
- BRWD3 | c.159C>G p.H53Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100955606; called by muse, mutect2, varscan2
- CCDC103 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763938078, COSV99492986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNB2 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99878897; called by muse, mutect2
- CETN1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV100511188; called by muse, mutect2, varscan2
- CR1 | c.4360C>T p.R1454* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs772663179, COSV100887362; called by muse, mutect2, varscan2
- CTNND1 | c.2152C>T p.L718F (on ENST00000399050 / NM_001085458.2; = p.L712F on NM_001331.3) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100649760; called by muse, mutect2, varscan2
- DCHS1 | c.3619A>G p.N1207D | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV100201398; called by muse, mutect2, varscan2
- DHX38 | c.2579C>T p.T860M | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372311072; called by muse, mutect2, varscan2
- DNAJC13 | c.2086A>G p.K696E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as COSV53452579; called by muse, mutect2, varscan2
- ENO2 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV99145116; called by muse, mutect2, varscan2
- FUT1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100037983; called by muse, mutect2, varscan2
- FZR1 | c.1361A>T p.D454V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100281250; called by muse, mutect2, varscan2
- HERC4 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV101034165; called by muse, mutect2, varscan2
- HSF2 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV100869625; called by muse, mutect2
- HTR3A | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100248237; called by muse, mutect2, varscan2
- IKZF1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100497909, COSV58789464; called by muse, mutect2
- IL32 | c.705A>G p.*235Wext*3 (on ENST00000396890 / NM_001308078.4; = p.*189Wext*3 on NM_004221.7 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99145451; called by muse, mutect2, varscan2
- IQCF1 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.084); catalogued as COSV100094795; called by muse, mutect2
- IRAK2 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs200632552, COSV99843591; called by muse, mutect2, varscan2
- ITGA8 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958759; called by muse, varscan2
- KEL | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs371010057; called by muse, mutect2, varscan2
- LAMA5 | c.450+2T>A p.X150_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99437728; called by muse, mutect2, varscan2
- LHX2 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV101010018; called by muse, mutect2, varscan2
- MAGI2 | c.2476G>C p.V826L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV62703920; called by muse, mutect2, varscan2
- MICAL3 | c.6009A>G p.*2003Wext*27 | Nonstop Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99349524; called by muse, mutect2, varscan2
- MMP10 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV99666307; called by muse, mutect2
- NBEA | c.8479C>T p.R2827C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs200699050; called by muse, mutect2, varscan2
- NPTX2 | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55716984, COSV99674670; called by muse, mutect2, varscan2
- OR1B1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs374643352; called by muse, mutect2, varscan2
- PCDHA3 | c.122A>T p.H41L | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV100973511; called by muse, mutect2, varscan2
- PFAS | c.3747T>G p.I1249M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100118731; called by muse, mutect2
- PORCN | c.1100G>A p.R367H (on ENST00000326194 / NM_203475.3; = p.R356H on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/116 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs781890070, COSV100400263; called by muse, mutect2, varscan2
- PPP6R2 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99323782; called by muse, mutect2, varscan2
- PREX2 | c.4120C>T p.R1374W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs267601977, COSV55763473; called by muse, mutect2, varscan2
- RIPK2 | c.989A>C p.E330A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99609635; called by muse, mutect2, varscan2
- SLC2A4 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768630770, COSV50301260; called by muse, mutect2, varscan2
- SLC7A2 | c.250C>G p.L84V (on ENST00000494857 / NM_001370338.1; = p.L124V on NM_003046.6) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99134289; called by muse, mutect2
- SPG11 | c.5165C>A p.S1722* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99967948; called by muse, mutect2
- TEX2 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99366732; called by muse, mutect2, varscan2
- UBAP1 | c.426_427del p.K143Sfs*15 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1563920252; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- USO1 | c.1884T>G p.I628M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99362489; called by muse, mutect2, varscan2
- WIF1 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.645); catalogued as COSV99682531; called by muse, mutect2, varscan2
- ZCCHC13 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100272447, COSV59865941; called by muse, mutect2, varscan2
- ZNF304 | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99988349; called by muse, mutect2, varscan2
- ABCC12 | c.3441G>A p.G1147= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100252099; called by muse, mutect2
- ARMC8 | c.1581G>T p.V527= (on ENST00000469044 / NM_001363941.2; = p.V513= on NM_015396.6) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100509376; called by muse, mutect2, varscan2
- CFAP43 | c.2736G>A p.A912= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs766514432, COSV53378499, COSV99531115; called by muse, mutect2, varscan2
- CTNND2 | c.1737T>C p.F579= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs749999355, COSV100471191; called by muse, mutect2, varscan2
- FANCA | c.2172G>A p.T724= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as rs768851944, COSV101224656; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXS1 | c.342C>T p.F114= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV99639424; called by muse, mutect2, varscan2
- GALNT12 | c.645G>C p.G215= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100899025; called by muse, mutect2, varscan2
- GLOD5 | c.87C>A p.T29= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1557016628, COSV100297384; called by muse, mutect2
- IGKV1-12 | c.294C>T p.S98= | Silent (SNP) | VAF 16/173 reads (9%) | catalogued as rs373615750; called by muse, mutect2
- IRS1 | c.927C>A p.T309= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100523936, COSV59336228; called by muse, mutect2, varscan2
- LACTB | c.495C>T p.I165= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99978808; called by muse, mutect2, varscan2
- LAMA5 | c.6027C>A p.G2009= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99437727; called by muse, mutect2
- MAGEB1 | c.621G>A p.V207= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1355924875, COSV100974816; called by muse, mutect2, varscan2
- MRGPRX3 | c.720C>G p.S240= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV101283478; called by muse, mutect2, varscan2
- POTEE | c.126C>T p.N42= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs558466498, COSV100386756; called by muse, mutect2, varscan2
- PSMB8 | c.816G>C p.R272= (on ENST00000374882 / NM_148919.4; = p.R268= on NM_004159.5) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV100841085; called by muse, mutect2, varscan2
- SALL1 | c.582C>T p.N194= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1270817273, COSV51759466; called by muse, mutect2, varscan2
- SLC12A5 | c.3156C>T p.I1052= (on ENST00000454036 / NM_001134771.2; = p.I1029= on NM_020708.5) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99275118; called by muse, mutect2, varscan2
- SLC29A4 | c.790C>A p.R264= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV51873024, COSV99786604; called by muse, mutect2, varscan2
- MAP4 | c.1999+5747A>G | Intron (SNP) | VAF 22/154 reads (14%) | catalogued as COSV99274596; called by muse, mutect2, varscan2
- PCDHA8 | c.-1C>T | 5'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100970386; called by muse, mutect2, varscan2
- PDLIM5 | c.920+619G>A | Intron (SNP) | VAF 16/32 reads (50%) | catalogued as rs1028454347, COSV58753283; called by muse, mutect2, varscan2
